Somatic mutation profile of tumor specimen C3L-02894-02 (aliquot CPT0196790007) from CPTAC case C3L-02894, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 67.8 years (24,775 days).
Specimen C3L-02894-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c82258ce-8f7a-4b2a-9f81-dcf9c59e5289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02894-31 (Blood Derived Normal), aliquot CPT0197780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca22b508-1480-40da-a086-530e9342b017

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, 5'Flank 2, In Frame Del 1, RNA 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.110_111del p.F37Sfs*6 | Frame Shift Del (DEL) | VAF 62/153 reads (41%) | catalogued as rs1114167636; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 164/304 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD12 | c.1428G>T p.L476F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV50819983, COSV50832774; called by muse, mutect2, varscan2
- CELF4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs767841321; called by muse, mutect2, varscan2
- EHD1 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs542855298; called by muse, mutect2, varscan2
- H2BW2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs202243976; called by muse, mutect2, varscan2
- KIF3B | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 222/485 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65226915; called by muse, mutect2, varscan2
- KRT74 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 40/547 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs148647777; called by muse, mutect2
- MED30 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52067733; called by muse, mutect2, varscan2
- MYO1F | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs777874239; called by muse, mutect2, varscan2
- NEFM | c.2506T>G p.L836V | Missense Mutation (SNP) | VAF 143/395 reads (36%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1473815198; called by muse, mutect2, varscan2
- NRDC | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.05); catalogued as rs1020464984; called by muse, mutect2, varscan2
- NUP62 | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1276909669; called by muse, mutect2, varscan2
- PARD3 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 188/531 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs553275668; called by muse, mutect2, varscan2
- RARS2 | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs200632524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC14L1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 145/790 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs757271773, COSV101170946; called by muse, mutect2, varscan2
- SLC23A3 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs1394451330; called by muse, mutect2, varscan2
- SP4 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1328629632, COSV56026153; called by muse, mutect2, varscan2
- C1orf112 | c.1545G>T p.E515D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CRK | c.875G>C p.R292P | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CUX1 | c.619dup p.T207Nfs*7 (on ENST00000292535 / NM_181552.4; = p.T218Nfs*7 on NM_001913.5) | Frame Shift Ins (INS) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- DPM2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IDH3G | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTCL1 | c.5375C>T p.A1792V (on ENST00000306329 / NM_001378206.1; = p.A1473V on NM_015210.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR14A16 | c.245A>T p.N82I | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RAB11FIP1 | c.2902G>T p.D968Y | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBR7 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF672 | c.1261_1272del p.R421_A424del | In Frame Del (DEL) | VAF 81/309 reads (26%) | called by mutect2, pindel, varscan2
- CUBN | c.5763C>T p.R1921= | Silent (SNP) | VAF 38/530 reads (7%) | catalogued as COSV64727859; called by muse, mutect2
- CYLC1 | c.315T>G p.T105= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- DPPA5 | c.282C>T p.R94= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- WWP2 | c.819T>G p.P273= | Silent (SNP) | VAF 90/156 reads (58%) | called by muse, mutect2, varscan2
- DCHS2 | n.6923C>T | RNA (SNP) | VAF 118/222 reads (53%) | catalogued as rs138058140; called by muse, mutect2, varscan2
- FANCC | c.-13C>T | 5'UTR (SNP) | VAF 156/301 reads (52%) | catalogued as rs1057521107; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBRS | chr16:30662644 A>G | 5'Flank (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159114 G>A | 5'Flank (SNP) | VAF 120/382 reads (31%) | catalogued as rs111958693; called by muse, mutect2, varscan2
- TTC19 | c.*1017G>A | 3'UTR (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
